Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5169, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5169-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

TCGA - BP - 5169

Specimens Submitted:

- 1: SP: Left kidney
- 2: SP: Portion of left eleventh rib
- 3: SP: Left spermatic vein
- 4: SP: Periaortic lymph node

DIAGNOSIS:

- 1) KIDNEY, LEFT; NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, NUCLEAR GRADE III/IV, WITH FOCAL AREAS OF NUCLEAR GRADE IV/IV.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR GREATEST DIAMETER IS 5.0 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- VASCULAR INVASION IS IDENTIFIED.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF CARCINOMA.
- THE NON-NEOPLASTIC KIDNEY SHOWS CHRONIC INFLAMMATION.
- THE ADRENAL GLAND IS NOT IDENTIFIED.
- 2) RIB, PORTION OF LEFT 11TH; EXCISION:
- BENIGN BONE AND TRILINEAGE MARROW WITH NORMAL MATURATION. ✓
- 3) SPERMATIC VEIN, LEFT; EXCISION:
- BENIGN VESSELS AND FIBROADIPOSE TISSUE.
- 4) LYMPH NODES, PERIAORTIC; EXCISION:
- NINE BENIGN LYMPH NODES (0/9).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result

Special Stain

Comment

RECUT

RECUT

Gross Description:

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

1) The specimen is received fresh for frozen section diagnosis, labeled, "Left kidney". It consists of a nephrectomy specimen, which includes perirenal adipose tissue and kidney. The adrenal gland is not identified. The ureter is identified measuring 9.5 cm in length. The urothelial lining appears to be unremarkable. The vascular margins are also identified. The kidney is bivalved and the cut surface shows a 5.0 x 3.5 x 3.5 cm well-circumscribed mass, located in the upper portion of the kidney. The tumor appears confined to the kidney, and compresses the adjacent renal parenchyma, pelvis and calyces. The tumor is abutting the renal capsule and the surrounding fat focally at the posterior aspect of the specimen. The rest of the adipose tissue is unremarkable. The rest of the renal parenchyma is also unremarkable. A representative section of the tumor is submitted for frozen section evaluation.

Summary of Sections:

FSC – frozen section control

UM – ureter margin

VM – vascular margin

T – tumor

N – uninvolved renal parenchyma

F – perirenal adipose tissue

2) The specimen is received in formalin, labeled "Portion of Left 11th Rib". It consists of a fragment of rib that measures 6.5 x 1 x 0.5 cm. The section is submitted for decalcification.

Summary of Sections:

U: undesignated

3) The specimen is received in formalin, labeled "Left Spermatic Vein". It consists of a 5 x 0.5 x 0.5 cm portion of tissue. On sectioning, a vessel is identified. Representative sections are submitted.

Summary of Sections:

U - undesignated

4) The specimen is received in formalin, labeled "Periaortic Lymph Node". It consists of multiple fragments of adipose tissue measuring in aggregate 4 x 1.5 x 1.5 cm. Upon dissection several lymph nodes are identified and entirely submitted.

Summary of Sections:

U - undesignated

Summary of Sections:

Part 1: SP: Left kidney

Block	Sect. Site	PCs
1	f	1
1	fsc	1
1	n	1
6	t	6
1	um	1
1	vm	1

Part 2: SP: Portion of left eleventh rib

Block	Sect. Site	PCs
1	U	1

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Part 3: SP: Left spermatic vein (sr)

Block	Sect. Site	PCs
1	U	4

Part 4: SP: Periaortic lymph node (sr)

Block	Sect. Site	PCs
5	U	8

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL CARCINOMA. [REDACTED]
PERMANENT DIAGNOSIS: SAME
- [REDACTED] [REDACTED]

Source: NCI Genomic Data Commons file f9aee6a3-f401-45ee-935a-e2a332f831b3 (TCGA-BP-5169.7CE50310-2932-479E-B969-3A0F3ECB1E70.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).